Somatic mutation profile of tumor specimen ALCH-AEOU-TTP1-A (aliquot ALCH-AEOU-TTP1-A-2-0-D-A612-36) from ALCHEMIST case ALCH-AEOU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 46.6 years (17,008 days).
Specimen ALCH-AEOU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdc169fa-2129-4b18-9c79-f5fd270f2183.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOU-NB1-A (Blood Derived Normal), aliquot ALCH-AEOU-NB1-A-1-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cca5a459-cc29-4893-93e6-7dbdb0a9716a

The open-access MAF lists 518 somatic variants for this specimen: 352 protein-altering or splice-affecting, 103 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 295, Silent 103, Nonsense Mutation 32, Intron 29, 3'UTR 10, RNA 9, Frame Shift Del 9, Splice Site 8, 5'UTR 7, 5'Flank 7, Splice Region 6, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4241A>G p.Y1414C | Missense Mutation (SNP) | VAF 138/583 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54325155; called by muse, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 216/946 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 198/882 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, varscan2
- ABCC8 | c.3989-2A>C p.X1330_splice | Splice Site (SNP) | VAF 140/416 reads (34%) | catalogued as CS137609; called by muse, mutect2, varscan2
- ACAN | c.1826G>A p.G609D | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs868746592; called by muse, mutect2, varscan2
- ACTN4 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.657); catalogued as rs372129305; called by muse, mutect2, varscan2
- ADAMTS16 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 130/492 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.924); catalogued as rs369272938; called by muse, mutect2, varscan2
- ADRA2A | c.445T>C p.S149P | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54527690; called by muse, mutect2, varscan2
- AFF3 | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs775211684, COSV57845950; called by muse, mutect2
- ALDH3B2 | c.657C>A p.C219* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as rs141364277; called by muse, mutect2, varscan2
- AOC3 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 125/549 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV53828792; called by muse, mutect2, varscan2
- AP4E1 | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs754108995; called by muse, mutect2, varscan2
- APOL5 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 193/713 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.25); catalogued as rs1192773487; called by muse, mutect2, varscan2
- ARHGAP35 | c.2456C>G p.S819C | Missense Mutation (SNP) | VAF 105/436 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as COSV101351823, COSV68333952; called by muse, mutect2, varscan2
- ASAP2 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 51/465 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1558380563, COSV99855899; called by muse, mutect2, varscan2
- ATP11B | c.2779A>T p.I927L | Missense Mutation (SNP) | VAF 262/673 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs908031230; called by muse, mutect2, varscan2
- ATP2A3 | c.2171C>A p.T724K | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99989038; called by muse, mutect2, varscan2
- BTNL8 | c.494C>A p.A165E | Missense Mutation (SNP) | VAF 96/333 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs370167264, COSV51458236; called by muse, mutect2, varscan2
- C2orf73 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.04); catalogued as rs1350007402, COSV58310944; called by muse, mutect2, varscan2
- CCDC142 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.796); catalogued as rs747544723; called by muse, mutect2, varscan2
- CCDC63 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 76/440 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as COSV100370285; called by muse, mutect2, varscan2
- CDH10 | c.2170G>C p.D724H | Missense Mutation (SNP) | VAF 126/574 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52582075, COSV52588300; called by muse, mutect2, varscan2
- CDH26 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54848129; called by muse, mutect2, varscan2
- CHD1 | c.1831A>G p.I611V | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs961613416; called by muse, mutect2, varscan2
- COL11A2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 90/495 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as rs760875506; called by muse, mutect2, varscan2
- COL13A1 | c.1055A>T p.K352M (on ENST00000398978 / NM_001130103.2; = p.K295M on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/371 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1191267818; called by muse, mutect2, varscan2
- COL22A1 | c.3092G>T p.G1031V | Missense Mutation (SNP) | VAF 114/310 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57347191; called by muse, mutect2, varscan2
- COL9A1 | c.697-1G>T p.X233_splice | Splice Site (SNP) | VAF 140/843 reads (17%) | catalogued as COSV57883086; called by muse, mutect2, varscan2
- CWH43 | c.1269A>T p.A423= | Splice Region (SNP) | VAF 74/246 reads (30%) | catalogued as rs777482501; called by muse, mutect2, varscan2
- DCBLD2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs573544033, COSV58787131, COSV58787820; called by muse, mutect2, varscan2
- DDX17 | c.760A>G p.R254G | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV53250791; called by muse, mutect2, varscan2
- DEFB119 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs772830343; called by muse, mutect2, varscan2
- DGKI | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 163/456 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55937741; called by muse, mutect2, varscan2
- DHX29 | c.3485G>A p.R1162Q | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs373269305; called by muse, varscan2
- DHX37 | c.3307G>T p.E1103* | Nonsense Mutation (SNP) | VAF 27/189 reads (14%) | catalogued as COSV100439374; called by muse, mutect2
- DNAH11 | c.12178C>A p.L4060M | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60938871; called by muse, mutect2, varscan2
- DPP10 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59686200; called by muse, mutect2, varscan2
- DZIP1L | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs1339780793; called by muse, mutect2, varscan2
- ERCC3 | c.2255G>A p.G752E | Missense Mutation (SNP) | VAF 156/520 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53427317; called by muse, mutect2, varscan2
- FSHR | c.1450del p.R484Afs*8 | Frame Shift Del (DEL) | VAF 72/240 reads (30%) | catalogued as COSV58627104; called by mutect2, pindel, varscan2
- FTCD | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs532226691, COSV52429347; called by muse, mutect2, varscan2
- G6PC2 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 195/671 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs148743304; called by muse, mutect2, varscan2
- GALNT17 | c.785G>C p.R262P | Missense Mutation (SNP) | VAF 161/536 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61155556; called by muse, mutect2, varscan2
- GALNT17 | c.1448C>A p.P483Q | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV61194630; called by muse, mutect2, varscan2
- GAS7 | c.1321G>T p.V441F (on ENST00000432992 / NM_201433.2; = p.V301F on NM_003644.3) | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs1195150810; called by muse, mutect2
- GLS | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV57841300; called by muse, mutect2, varscan2
- GMPS | c.1669G>A p.V557I | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs368366043; called by muse, mutect2, varscan2
- GNPTG | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113167728; called by muse, mutect2, varscan2
- HCN1 | c.2097C>A p.Y699* | Nonsense Mutation (SNP) | VAF 92/409 reads (22%) | catalogued as COSV100303192; called by muse, mutect2, varscan2
- HRH2 | c.865G>C p.A289P | Missense Mutation (SNP) | VAF 108/297 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.289); catalogued as COSV99039862; called by muse, mutect2, varscan2
- HTR1B | c.779C>A p.S260Y | Missense Mutation (SNP) | VAF 105/412 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757059851; called by muse, mutect2, varscan2
- IGSF1 | c.3185G>T p.G1062V | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63837543; called by muse, mutect2, varscan2
- IL12RB1 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1351300101; called by muse, mutect2
- INTS7 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772978317; called by muse, mutect2, varscan2
- ITGBL1 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 93/304 reads (31%) | catalogued as COSV65960936; called by muse, mutect2, varscan2
- JAK3 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 152/690 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV71687119; called by muse, mutect2, varscan2
- KAT8 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 36/212 reads (17%) | catalogued as COSV99571328; called by muse, mutect2, varscan2
- KCNA6 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54974601; called by muse, mutect2, varscan2
- KCNN2 | c.1518G>C p.R506S (on ENST00000264773; = p.R718S on NM_021614.4) | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV53290201; called by muse, mutect2, varscan2
- KCNT2 | c.864del p.G289Efs*21 | Frame Shift Del (DEL) | VAF 96/418 reads (23%) | catalogued as COSV54111090; called by mutect2, pindel, varscan2
- LRRIQ1 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1242457714; called by muse, mutect2, varscan2
- MAGED1 | c.1477A>T p.K493* | Nonsense Mutation (SNP) | VAF 86/164 reads (52%) | catalogued as COSV58515113; called by muse, mutect2, varscan2
- MAGI2 | c.2884C>G p.P962A | Missense Mutation (SNP) | VAF 103/449 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62641903; called by muse, mutect2, varscan2
- MALRD1 | c.3479C>A p.T1160K | Missense Mutation (SNP) | VAF 157/377 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs545887640, COSV65982370; called by muse, mutect2, varscan2
- MARCO | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 119/360 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.172); catalogued as COSV59051517; called by muse, mutect2, varscan2
- MINDY2 | c.604C>G p.P202A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV100376639; called by muse, mutect2
- MROH2B | c.901A>C p.S301R | Missense Mutation (SNP) | VAF 114/330 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.22); catalogued as COSV101270457; called by muse, mutect2, varscan2
- MUC7 | c.851C>A p.P284Q | Missense Mutation (SNP) | VAF 185/883 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as rs749269416, COSV59218095; called by muse, mutect2, varscan2
- MYO16 | c.2414A>G p.Y805C | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1423575215; called by muse, varscan2
- OCA2 | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 164/795 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62357436; called by muse, mutect2, varscan2
- OCA2 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 91/589 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV62355676; called by muse, mutect2, varscan2
- OPCML | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV99045621; called by muse, mutect2, varscan2
- OR2AK2 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV63557880; called by muse, mutect2, varscan2
- OR4C6 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 131/587 reads (22%) | catalogued as rs570747653; called by muse, mutect2, varscan2
- OR5L2 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 123/452 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs751903198, COSV65724399; called by muse, mutect2, varscan2
- OR7D4 | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs1262124744; called by muse, mutect2, varscan2
- PDE1A | c.874C>G p.H292D | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59515408; called by muse, mutect2, varscan2
- PFN4 | c.331A>G p.S111G | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1194635418; called by muse, mutect2, varscan2
- PIGL | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51985452; called by muse, mutect2
- PNLIP | c.404C>G p.S135W | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65040591; called by muse, mutect2, varscan2
- POLRMT | c.2426G>C p.C809S | Missense Mutation (SNP) | VAF 85/393 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52117321; called by muse, mutect2, varscan2
- PON3 | c.233C>A p.A78E | Missense Mutation (SNP) | VAF 124/584 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as COSV55700808; called by muse, mutect2, varscan2
- POTEC | c.1626C>A p.N542K | Missense Mutation (SNP) | VAF 101/422 reads (24%) | PolyPhen benign (0); catalogued as COSV62806053; called by muse, mutect2, varscan2
- PPARGC1A | c.2216G>T p.R739L | Missense Mutation (SNP) | VAF 91/489 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs145169644, COSV53531861, COSV53532310; called by muse, mutect2, varscan2
- PRB3 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs369472544; called by muse, mutect2, varscan2
- PTCH2 | c.741C>A p.Y247* | Nonsense Mutation (SNP) | VAF 25/43 reads (58%) | catalogued as rs771872936, COSV100942334; called by muse, mutect2, varscan2
- RASEF | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370500066; called by muse, mutect2, varscan2
- RASSF4 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs985026918; called by muse, mutect2, varscan2
- RBMXL2 | c.1042C>A p.R348S | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs774245349, COSV60978494, COSV60981517; called by muse, mutect2, varscan2
- RNF111 | c.2547A>C p.L849F | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.755); catalogued as rs780247073; called by muse, mutect2, varscan2
- RNF39 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as rs1425886109; called by muse, mutect2, varscan2
- RTKN2 | c.1349T>C p.I450T | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV104408829; called by mutect2, varscan2
- SAGE1 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs782693913, COSV61013935; called by muse, mutect2, varscan2
- SCN3A | c.5258G>T p.S1753I | Missense Mutation (SNP) | VAF 97/594 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV51815482, COSV51822947; called by muse, mutect2, varscan2
- SEMA5A | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs200292451; called by muse, mutect2, varscan2
- SERPINB8 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 127/334 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54639900, COSV54640412; called by muse, mutect2, varscan2
- SIGLEC5 | c.546del p.N183Mfs*33 | Frame Shift Del (DEL) | VAF 32/176 reads (18%) | catalogued as COSV99707411; called by mutect2, varscan2
- SLC17A3 | c.1088C>G p.P363R | Missense Mutation (SNP) | VAF 147/544 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100399235; called by muse, mutect2, varscan2
- SLC35F1 | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64498566; called by muse, mutect2, varscan2
- SLC4A10 | c.2474C>A p.T825N (on ENST00000446997 / NM_001354461.2; = p.T795N on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55805171; called by muse, mutect2, varscan2
- SLCO1B1 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99918570; called by muse, mutect2, varscan2
- SMO | c.766T>C p.W256R | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50826472; called by muse, mutect2, varscan2
- SND1 | c.79-1G>C p.X27_splice | Splice Site (SNP) | VAF 40/151 reads (26%) | catalogued as COSV61238523; called by muse, mutect2
- SPEF2 | c.3767C>A p.T1256N | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV100606034; called by muse, varscan2
- SPON1 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 69/188 reads (37%) | catalogued as rs781888656, COSV59958544; called by muse, mutect2, varscan2
- SPTLC1 | c.24G>T p.W8C | Missense Mutation (SNP) | VAF 272/575 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV52763748; called by muse, mutect2, varscan2
- SV2A | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368258942; called by muse, mutect2, varscan2
- TAAR1 | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs548545478; called by muse, mutect2, varscan2
- THSD7B | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 148/524 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.697); catalogued as rs752449766; called by muse, varscan2
- TNC | c.4735G>T p.G1579* | Nonsense Mutation (SNP) | VAF 129/545 reads (24%) | catalogued as COSV60787850; called by muse, mutect2, varscan2
- TRHDE | c.1827A>T p.E609D | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1441789714, COSV53840363; called by muse, mutect2
- TRIM46 | c.975G>C p.E325D | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV55279016; called by muse, mutect2, varscan2
- TTN | c.43904T>C p.I14635T (on ENST00000591111; = p.I7211T on NM_003319.4) | Missense Mutation (SNP) | VAF 55/169 reads (33%) | PolyPhen probably damaging (0.996); catalogued as rs759916327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.3875G>A p.G1292E (on ENST00000591111; = p.G1246E on NM_003319.4) | Missense Mutation (SNP) | VAF 77/426 reads (18%) | PolyPhen possibly damaging (0.55); catalogued as COSV60080156; called by muse, mutect2, varscan2
- TVP23C | c.26A>T p.D9V | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV56669500; called by muse, mutect2, varscan2
- WSCD2 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 34/193 reads (18%) | catalogued as COSV54584027; called by muse, mutect2, varscan2
- ZNF131 | c.1724A>T p.E575V (on ENST00000509156 / NM_001330707.2; = p.E541V on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 156/723 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as rs748444366; called by muse, mutect2, varscan2
- ZNF343 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99601272; called by muse, mutect2, varscan2
- ZNF445 | c.3067C>T p.R1023W | Missense Mutation (SNP) | VAF 166/493 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs777987649; called by muse, mutect2, varscan2
- ZSCAN23 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1561978403; called by muse, mutect2, varscan2
- ADAMTS6 | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3351C>A p.D1117E | Missense Mutation (SNP) | VAF 211/382 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4285G>T p.E1429* | Nonsense Mutation (SNP) | VAF 50/178 reads (28%) | called by muse, mutect2, varscan2
- ADCY7 | c.2185G>T p.G729C | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ADGRA2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, varscan2
- ADGRB2 | c.839-2A>G p.X280_splice | Splice Site (SNP) | VAF 91/286 reads (32%) | called by muse, mutect2, varscan2
- AFDN | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- AFF3 | c.2098G>T p.A700S | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2
- AGAP6 | c.244G>T p.A82S (on ENST00000374056 / NM_001365867.1; = p.A105S on NM_001077665.2) | Missense Mutation (SNP) | VAF 57/523 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- AGMO | c.1195A>T p.M399L | Missense Mutation (SNP) | VAF 79/466 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMIGO1 | c.913A>C p.S305R | Missense Mutation (SNP) | VAF 133/389 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANK2 | c.9227_9228del p.Q3076Rfs*5 | Frame Shift Del (DEL) | VAF 60/212 reads (28%) | called by mutect2, pindel, varscan2
- APOB | c.2537T>A p.L846* | Nonsense Mutation (SNP) | VAF 142/440 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 73/358 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARL14 | c.273T>A p.S91R | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ASB2 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 196/658 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ASTN2 | c.3766G>C p.D1256H (on ENST00000313400 / NM_001365069.1; = p.D1205H on NM_014010.5) | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASXL3 | c.6541G>A p.G2181S | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASXL3 | c.6542G>T p.G2181V | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ATG12 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 120/344 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ATN1 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATP6V1C2 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 79/614 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B4GALNT1 | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2
- B4GALT1 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 451/802 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BICD1 | c.2779G>C p.A927P | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRINP3 | c.392del p.Y131Lfs*26 | Frame Shift Del (DEL) | VAF 80/310 reads (26%) | called by mutect2, pindel, varscan2
- BSN | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 96/272 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BUB1B | c.2143G>T p.E715* | Nonsense Mutation (SNP) | VAF 78/631 reads (12%) | called by muse, mutect2, varscan2
- CACNA1S | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 296/1005 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CARMIL3 | c.1737T>A p.N579K | Missense Mutation (SNP) | VAF 104/279 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCDC168 | c.5002G>T p.G1668C | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CCR9 | c.500T>C p.M167T (on ENST00000357632 / NM_031200.3; = p.M155T on NM_006641.4) | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CCT8L2 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 76/351 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH4 | c.675G>T p.M225I | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH6 | c.1005G>T p.L335F | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CDH6 | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 145/714 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CEP170 | c.4570G>T p.V1524L | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CFAP61 | c.3302C>A p.T1101K | Missense Mutation (SNP) | VAF 161/672 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFH | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 100/355 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CHST8 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC2L | c.433-1G>T p.X145_splice | Splice Site (SNP) | VAF 172/718 reads (24%) | called by muse, varscan2
- CNKSR2 | c.228+5G>T | Splice Region (SNP) | VAF 126/211 reads (60%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2351A>G p.Y784C | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- CNTNAP5 | c.2965T>A p.Y989N | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, varscan2
- COL3A1 | c.4228T>C p.Y1410H | Missense Mutation (SNP) | VAF 87/492 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COX4I2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 162/680 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, varscan2
- CPLANE1 | c.8471G>T p.G2824V | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- CRIM1 | c.284del p.P95Rfs*41 | Frame Shift Del (DEL) | VAF 48/185 reads (26%) | called by mutect2, pindel
- CRISP3 | c.131G>T p.G44V (on ENST00000371159 / NM_001368123.1; = p.G26V on NM_006061.4) | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CROCC | c.4630G>T p.A1544S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CUL7 | c.1535T>A p.V512D | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2
- CYP11B1 | c.1424C>G p.T475R | Missense Mutation (SNP) | VAF 99/903 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DACH1 | c.1105G>C p.G369R | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- DCAF4L2 | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 78/581 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DCAF5 | c.2422G>T p.G808W | Missense Mutation (SNP) | VAF 88/232 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- DCDC2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- DES | c.584A>T p.Q195L | Missense Mutation (SNP) | VAF 234/839 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- DLC1 | c.498A>G p.I166M | Missense Mutation (SNP) | VAF 145/333 reads (44%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH7 | c.8756G>T p.G2919V | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOHH | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DOK4 | c.863-8G>A | Splice Region (SNP) | VAF 81/606 reads (13%) | called by muse, mutect2, varscan2
- DSC1 | c.2326A>G p.T776A | Missense Mutation (SNP) | VAF 173/768 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- EPB41 | c.776C>T p.A259V (on ENST00000343067 / NM_001166005.2; = p.A50V on NM_004437.4) | Missense Mutation (SNP) | VAF 154/432 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPB41L3 | c.3161C>A p.A1054D | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EPB41L3 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 171/666 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ERN1 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESCO2 | c.1156dup p.A386Gfs*17 | Frame Shift Ins (INS) | VAF 224/629 reads (36%) | called by mutect2, pindel, varscan2
- EXOC1 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- FASTKD3 | c.1700-5A>T | Splice Region (SNP) | VAF 69/235 reads (29%) | called by muse, mutect2, varscan2
- FAT4 | c.8477C>G p.T2826R | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAXC | c.509A>T p.K170M | Missense Mutation (SNP) | VAF 90/336 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- FOXD3 | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FOXI3 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 66/515 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRYL | c.8255T>A p.L2752Q | Missense Mutation (SNP) | VAF 228/802 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FUT6 | c.838T>G p.Y280D | Missense Mutation (SNP) | VAF 109/613 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FYN | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GAB4 | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- GAS7 | c.882del p.K295Sfs*10 (on ENST00000432992 / NM_201433.2; = p.K155Sfs*10 on NM_003644.3) | Frame Shift Del (DEL) | VAF 76/337 reads (23%) | called by mutect2, pindel, varscan2
- GIMAP7 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 157/498 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- GIPC2 | c.271A>C p.I91L | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, varscan2
- GLYATL3 | c.84C>G p.Y28* | Nonsense Mutation (SNP) | VAF 84/268 reads (31%) | called by muse, varscan2
- GNAS | c.719dup p.L242Afs*53 | Frame Shift Ins (INS) | VAF 166/886 reads (19%) | called by mutect2, pindel, varscan2
- GPR75 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 152/399 reads (38%) | called by muse, mutect2, varscan2
- GREB1 | c.1635C>G p.N545K | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GRIN3A | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 87/399 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GRM3 | c.1943T>C p.L648P | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM4 | c.1742T>A p.L581H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM8 | c.1637A>G p.Y546C | Missense Mutation (SNP) | VAF 128/580 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- GRXCR1 | c.264T>A p.S88R | Missense Mutation (SNP) | VAF 157/678 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSTA2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.024); called by muse, varscan2
- GXYLT1 | c.1145A>C p.Y382S | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- HLCS | c.1356C>A p.N452K | Missense Mutation (SNP) | VAF 252/484 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- HNRNPM | c.1430A>T p.E477V | Missense Mutation (SNP) | VAF 90/444 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IDH1 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- IGHV3-74 | c.83del p.G28Efs*3 | Frame Shift Del (DEL) | VAF 68/432 reads (16%) | called by mutect2, pindel, varscan2
- IGHV6-1 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 302/721 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV3D-11 | c.221G>T p.R74M | Missense Mutation (SNP) | VAF 90/650 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IGLON5 | c.577T>A p.Y193N | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPR2 | c.6508G>C p.E2170Q | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ITPRID1 | c.767T>A p.L256H | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JMJD1C | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KALRN | c.7660C>G p.H2554D (on ENST00000360013 / NM_001024660.4; = p.H857D on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/502 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KALRN | c.8213C>A p.P2738H (on ENST00000360013 / NM_001024660.4; = p.P1041H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/633 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KAT6A | c.3799G>C p.E1267Q | Missense Mutation (SNP) | VAF 165/333 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.177); called by muse, varscan2
- KCNB2 | c.2492C>A p.P831Q | Missense Mutation (SNP) | VAF 205/458 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KCNN2 | c.1517G>T p.R506M (on ENST00000264773; = p.R718M on NM_021614.4) | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, varscan2
- KIAA1549 | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 206/587 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIF1C | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIRREL2 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- KLHL1 | c.977G>T p.C326F | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL1 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 76/414 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KMT2D | c.12715C>T p.Q4239* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- LARP4B | c.844_845del p.E282Sfs*2 | Frame Shift Del (DEL) | VAF 77/228 reads (34%) | called by mutect2, pindel, varscan2
- LGI1 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 315/750 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, varscan2
- LGMN | c.712A>T p.M238L | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- LMTK2 | c.3888G>T p.E1296D | Missense Mutation (SNP) | VAF 103/360 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP1 | c.10790A>G p.D3597G | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1B | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 201/555 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC42 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LRRC69 | c.375A>T p.E125D | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- LYSMD1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 120/502 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MACF1 | c.5435A>G p.Q1812R | Missense Mutation (SNP) | VAF 207/438 reads (47%) | called by muse, mutect2, varscan2
- MALRD1 | c.2991G>T p.Q997H | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, varscan2
- MAP2K2 | c.699C>A p.Y233* | Nonsense Mutation (SNP) | VAF 48/168 reads (29%) | called by muse, mutect2, varscan2
- MCTP1 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- MDC1 | c.1330C>G p.R444G | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MDGA2 | c.1941G>T p.L647F (on ENST00000399232 / NM_001113498.2; = p.L349F on NM_182830.4) | Missense Mutation (SNP) | VAF 252/645 reads (39%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- MEGF9 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); called by muse, varscan2
- MGAT5 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 103/410 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MMP24 | c.1796C>A p.S599Y | Missense Mutation (SNP) | VAF 174/774 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- MRPS6 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 20/354 reads (6%) | called by muse, mutect2
- MSC | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSTN | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC15 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 133/433 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MUC19 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYH1 | c.5179C>A p.L1727M | Missense Mutation (SNP) | VAF 106/466 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NAV3 | c.730A>T p.K244* | Nonsense Mutation (SNP) | VAF 66/277 reads (24%) | called by muse, mutect2, varscan2
- NKAIN4 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NKRF | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 142/271 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- NPHP3 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OBSCN | c.22828T>G p.C7610G | Missense Mutation (SNP) | VAF 100/403 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- OPN4 | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10X1 | c.212T>A p.L71H | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11H2 | c.520G>A p.G174S (on ENST00000556246; = p.G185S on NM_001197287.1) | Missense Mutation (SNP) | VAF 297/1587 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OR11L1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 214/626 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR1G1 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4C11 | c.636G>T p.L212F | Missense Mutation (SNP) | VAF 129/443 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- OR4D5 | c.795C>A p.F265L | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR6X1 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ORM1 | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 429/978 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- PASD1 | c.1831G>T p.V611F | Missense Mutation (SNP) | VAF 150/272 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PCDHB2 | c.1721G>C p.C574S | Missense Mutation (SNP) | VAF 123/660 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDHGA12 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCLO | c.8136G>T p.K2712N | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- PCTP | c.608T>C p.M203T | Missense Mutation (SNP) | VAF 75/300 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PDE10A | c.1656G>T p.E552D | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PDE10A | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 56/393 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZD8 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 123/242 reads (51%) | called by muse, mutect2, varscan2
- PGAM4 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 227/447 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PIK3R6 | c.2156C>A p.S719Y | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- PKD1L2 | c.2477C>A p.S826* | Nonsense Mutation (SNP) | VAF 44/284 reads (15%) | called by muse, mutect2, varscan2
- PLCE1 | c.763C>G p.H255D | Missense Mutation (SNP) | VAF 36/590 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2
- PLCE1 | c.3858G>C p.K1286N | Missense Mutation (SNP) | VAF 294/593 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PLCG2 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PLD5 | c.632T>A p.M211K (on ENST00000442594; = p.M149K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- POTEE | c.118A>T p.K40* | Nonsense Mutation (SNP) | VAF 130/967 reads (13%) | called by muse, mutect2, varscan2
- POU2F1 | c.680A>G p.Q227R (on ENST00000541643 / NM_001365848.1; = p.Q250R on NM_002697.4) | Missense Mutation (SNP) | VAF 125/482 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, varscan2
- PPP1R12C | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- PPP1R9A | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PPRC1 | c.3844G>A p.G1282R | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRLHR | c.976A>C p.S326R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PSEN2 | c.142-5C>A | Splice Region (SNP) | VAF 188/616 reads (31%) | called by muse, mutect2, varscan2
- PTGIR | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PTPRN2 | c.669G>C p.Q223H | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.275); called by muse, mutect2
- RASAL2 | c.351T>G p.H117Q | Missense Mutation (SNP) | VAF 117/398 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RELN | c.4580G>A p.R1527K | Missense Mutation (SNP) | VAF 132/517 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RFX4 | c.1525C>G p.P509A (on ENST00000392842 / NM_213594.3; = p.P415A on NM_032491.6) | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RHBDL3 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF214 | c.1174C>G p.R392G | Missense Mutation (SNP) | VAF 118/385 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SARDH | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 143/342 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SCN1A | c.3722A>G p.Y1241C (on ENST00000303395 / NM_001202435.3; = p.Y1230C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SCN9A | c.3676C>A p.L1226M (on ENST00000303354; = p.L1215M on NM_002977.3) | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- SIM1 | c.1567C>A p.H523N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, varscan2
- SLC14A2 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC17A1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC22A2 | c.1387A>C p.R463= | Splice Region (SNP) | VAF 90/316 reads (28%) | called by muse, mutect2, varscan2
- SLC38A8 | c.994G>T p.G332* | Nonsense Mutation (SNP) | VAF 36/317 reads (11%) | called by muse, mutect2, varscan2
- SLC49A4 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); called by muse, mutect2
- SLC6A12 | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 105/375 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SMG1 | c.8229A>C p.K2743N | Missense Mutation (SNP) | VAF 115/473 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SNX30 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 72/167 reads (43%) | called by muse, mutect2, varscan2
- SPATA6L | c.1166A>G p.Q389R (on ENST00000461761 / NM_001353484.2; = p.Q331R on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 161/279 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SPDYE4 | c.400-1G>T p.X134_splice | Splice Site (SNP) | VAF 46/283 reads (16%) | called by muse, mutect2, varscan2
- SPIRE1 | c.1777-1G>T p.X593_splice (on ENST00000409402 / NM_001128626.2; = p.X579_splice on NM_020148.3) | Splice Site (SNP) | VAF 54/204 reads (26%) | called by muse, mutect2, varscan2
- SPTA1 | c.1488+1G>T p.X496_splice | Splice Site (SNP) | VAF 209/776 reads (27%) | called by muse, mutect2, varscan2
- SRGAP1 | c.3107G>T p.S1036I | Missense Mutation (SNP) | VAF 103/348 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- STAT5A | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 94/368 reads (26%) | called by muse, mutect2, varscan2
- STXBP5 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SYNE1 | c.17100G>T p.E5700D (on ENST00000367255 / NM_182961.4; = p.E5629D on NM_033071.3) | Missense Mutation (SNP) | VAF 56/452 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBX19 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 207/1048 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM3 | c.2182G>T p.E728* | Nonsense Mutation (SNP) | VAF 68/167 reads (41%) | called by muse, mutect2, varscan2
- TMEM199 | c.384A>C p.R128S | Missense Mutation (SNP) | VAF 70/376 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMOD4 | c.123G>C p.E41D | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TPGS2 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 48/190 reads (25%) | called by muse, mutect2, varscan2
- TPH2 | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 107/728 reads (15%) | called by muse, mutect2, varscan2
- TPSAB1 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, varscan2
- TRAPPC3L | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 112/414 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRIM43 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 74/614 reads (12%) | called by muse, varscan2
- TRIM61 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- TTN | c.100583T>A p.L33528Q (on ENST00000591111; = p.L26104Q on NM_003319.4) | Missense Mutation (SNP) | VAF 120/409 reads (29%) | PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TTN | c.56992T>A p.Y18998N (on ENST00000591111; = p.Y11574N on NM_003319.4) | Missense Mutation (SNP) | VAF 98/587 reads (17%) | PolyPhen benign (0.44); called by muse, mutect2, varscan2
- TTN | c.14831C>A p.A4944D (on ENST00000591111; = p.A4017D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBA3E | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TUBB8B | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 264/1376 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- UGT2B15 | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- UMPS | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 134/312 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.4595G>T p.S1532I | Missense Mutation (SNP) | VAF 133/398 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- USH2A | c.3691A>T p.S1231C | Missense Mutation (SNP) | VAF 120/421 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- USP17L2 | c.1074C>G p.S358R | Missense Mutation (SNP) | VAF 459/1145 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- USPL1 | c.550A>T p.T184S | Missense Mutation (SNP) | VAF 165/394 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VCAM1 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 157/382 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- WDR26 | c.817G>A p.D273N (on ENST00000414423 / NM_001379403.1; = p.D173N on NM_025160.7) | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF10 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF260 | c.449A>T p.Y150F | Missense Mutation (SNP) | VAF 106/447 reads (24%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- ZNF268 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.224); called by muse, varscan2
- ZNF292 | c.6524A>G p.Q2175R | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF385B | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ZNF470 | c.934T>A p.Y312N | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF547 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 107/325 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZNF697 | c.1029C>A p.S343R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF765 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | called by muse, varscan2
- ZNF99 | c.2264A>G p.H755R | Missense Mutation (SNP) | VAF 99/451 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ACSM3 | c.192C>A p.V64= | Silent (SNP) | VAF 112/347 reads (32%) | called by muse, mutect2, varscan2
- ADGRV1 | c.7692T>C p.N2564= | Silent (SNP) | VAF 245/623 reads (39%) | called by muse, mutect2, varscan2
- ANKFN1 | c.744G>T p.L248= | Silent (SNP) | VAF 102/359 reads (28%) | catalogued as COSV100593614; called by muse, mutect2, varscan2
- APBA2 | c.843C>G p.P281= | Silent (SNP) | VAF 103/390 reads (26%) | called by muse, mutect2, varscan2
- APC | c.7446A>C p.P2482= | Silent (SNP) | VAF 82/226 reads (36%) | catalogued as rs780091029; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGEF11 | c.3474A>G p.E1158= | Silent (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- ASB10 | c.48C>T p.P16= | Silent (SNP) | VAF 24/170 reads (14%) | called by muse, varscan2
- ATRX | c.7464A>G p.Q2488= | Silent (SNP) | VAF 79/162 reads (49%) | catalogued as COSV64881294; called by muse, mutect2, varscan2
- B3GNT6 | c.321A>G p.A107= | Silent (SNP) | VAF 65/194 reads (34%) | called by muse, mutect2, varscan2
- BCAM | c.879G>T p.G293= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV54301395; called by muse, mutect2, varscan2
- BRINP1 | c.363C>T p.I121= | Silent (SNP) | VAF 101/180 reads (56%) | called by muse, mutect2, varscan2
- C3AR1 | c.786T>C p.A262= | Silent (SNP) | VAF 92/304 reads (30%) | called by muse, mutect2, varscan2
- CACNA1E | c.5979G>A p.A1993= | Silent (SNP) | VAF 32/303 reads (11%) | catalogued as rs201021616, COSV62425963; called by muse, mutect2, varscan2
- CAPN6 | c.1599C>A p.A533= | Silent (SNP) | VAF 65/122 reads (53%) | called by muse, mutect2, varscan2
- CARD6 | c.1563C>T p.P521= | Silent (SNP) | VAF 69/298 reads (23%) | catalogued as COSV54566547; called by muse, varscan2
- CD200R1 | c.585T>C p.N195= (on ENST00000471858 / NM_170780.3; = p.N218= on NM_138806.4) | Silent (SNP) | VAF 342/940 reads (36%) | called by muse, mutect2, varscan2
- CD5L | c.273C>T p.I91= | Silent (SNP) | VAF 116/722 reads (16%) | catalogued as rs374773038; called by muse, mutect2, varscan2
- CFAP65 | c.3717C>T p.S1239= | Silent (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2, varscan2
- CIP2A | c.435G>C p.T145= | Silent (SNP) | VAF 33/141 reads (23%) | called by muse, mutect2, varscan2
- CRISPLD1 | c.1425T>C p.S475= | Silent (SNP) | VAF 54/360 reads (15%) | called by muse, mutect2, varscan2
- CTSE | c.198C>T p.A66= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs1553278678; called by muse, mutect2, varscan2
- CUL4A | c.1479C>T p.G493= (on ENST00000375440 / NM_001008895.4; = p.G393= on NM_003589.3) | Silent (SNP) | VAF 130/424 reads (31%) | called by muse, mutect2, varscan2
- DNAH8 | c.4146T>G p.L1382= | Silent (SNP) | VAF 136/411 reads (33%) | catalogued as COSV59464742; called by muse, mutect2, varscan2
- DSG1 | c.297C>A p.I99= | Silent (SNP) | VAF 105/547 reads (19%) | catalogued as COSV57133936; called by muse, mutect2, varscan2
- DZIP3 | c.2337A>G p.Q779= | Silent (SNP) | VAF 49/224 reads (22%) | called by muse, mutect2, varscan2
- ELMO1 | c.324C>A p.A108= | Silent (SNP) | VAF 49/268 reads (18%) | called by muse, mutect2, varscan2
- ELMO1 | c.90G>A p.L30= | Silent (SNP) | VAF 74/268 reads (28%) | catalogued as rs1470575123; called by muse, varscan2
- EMX1 | c.309C>A p.A103= | Silent (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- ERBB3 | c.2907C>T p.A969= | Silent (SNP) | VAF 206/624 reads (33%) | called by muse, mutect2, varscan2
- FAM170A | c.372G>A p.R124= | Silent (SNP) | VAF 127/308 reads (41%) | called by muse, mutect2, varscan2
- FAM83A | c.1215G>A p.R405= | Silent (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- FANCC | c.805C>T p.L269= | Silent (SNP) | VAF 376/766 reads (49%) | called by muse, mutect2, varscan2
- FBN3 | c.4665C>T p.N1555= | Silent (SNP) | VAF 49/163 reads (30%) | catalogued as rs1472445388, COSV54452600; called by muse, mutect2, varscan2
- FKRP | c.441G>T p.A147= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- FLG2 | c.1566G>A p.G522= | Silent (SNP) | VAF 36/532 reads (7%) | called by muse, mutect2
- GPR156 | c.1821G>T p.R607= | Silent (SNP) | VAF 78/232 reads (34%) | called by muse, mutect2, varscan2
- GRB10 | c.1701G>C p.L567= (on ENST00000398812; = p.L521= on NM_001001549.3) | Silent (SNP) | VAF 148/790 reads (19%) | called by muse, mutect2, varscan2
- HCN1 | c.669G>T p.V223= | Silent (SNP) | VAF 136/529 reads (26%) | called by muse, mutect2, varscan2
- HOXA3 | c.321C>A p.P107= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs1438047631; called by muse, mutect2, varscan2
- HSPG2 | c.264G>T p.V88= | Silent (SNP) | VAF 236/682 reads (35%) | called by muse, mutect2, varscan2
- IGSF11 | c.1092G>T p.L364= (on ENST00000393775 / NM_001015887.3; = p.L363= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 291/683 reads (43%) | called by muse, mutect2, varscan2
- IL21R | c.1371G>A p.E457= | Silent (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- IRAK3 | c.927A>G p.L309= | Silent (SNP) | VAF 102/262 reads (39%) | called by muse, mutect2, varscan2
- JAK3 | c.1645C>A p.R549= | Silent (SNP) | VAF 152/679 reads (22%) | called by muse, mutect2, varscan2
- KALRN | c.8214C>A p.P2738= (on ENST00000360013 / NM_001024660.4; = p.P1041= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/631 reads (14%) | called by muse, mutect2, varscan2
- LGI1 | c.1224T>C p.P408= | Silent (SNP) | VAF 314/750 reads (42%) | called by muse, varscan2
- LRP2 | c.1755T>A p.T585= | Silent (SNP) | VAF 124/421 reads (29%) | called by muse, mutect2, varscan2
- LRP4 | c.3651T>A p.T1217= | Silent (SNP) | VAF 223/537 reads (42%) | called by muse, mutect2, varscan2
- LRRN3 | c.1222C>A p.R408= | Silent (SNP) | VAF 69/230 reads (30%) | catalogued as COSV57821979; called by muse, mutect2, varscan2
- MBP | c.444C>T p.Y148= (on ENST00000355994 / NM_001025101.2; = p.Y15= on NM_002385.3) | Silent (SNP) | VAF 178/633 reads (28%) | called by muse, mutect2, varscan2
- MDC1 | c.2824C>T p.L942= | Silent (SNP) | VAF 95/435 reads (22%) | called by muse, mutect2, varscan2
- MGAT3 | c.834G>C p.P278= | Silent (SNP) | VAF 69/295 reads (23%) | called by muse, mutect2, varscan2
- MLYCD | c.1296C>T p.R432= | Silent (SNP) | VAF 59/168 reads (35%) | catalogued as rs369624204; called by muse, mutect2, varscan2
- MMP24 | c.1797C>A p.S599= | Silent (SNP) | VAF 175/773 reads (23%) | catalogued as COSV55771754; called by muse, mutect2, varscan2
- MS4A14 | c.63T>C p.T21= | Silent (SNP) | VAF 104/315 reads (33%) | called by muse, mutect2, varscan2
- MYH4 | c.792A>T p.A264= | Silent (SNP) | VAF 46/180 reads (26%) | called by muse, mutect2, varscan2
- MYLK | c.1062G>T p.P354= | Silent (SNP) | VAF 114/526 reads (22%) | called by muse, mutect2, varscan2
- NCEH1 | c.1068T>C p.L356= (on ENST00000538775; = p.L316= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/491 reads (18%) | called by muse, mutect2, varscan2
- NEFM | c.2418A>T p.V806= | Silent (SNP) | VAF 225/566 reads (40%) | called by muse, mutect2, varscan2
- NEIL1 | c.405C>T p.P135= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- NPY1R | c.822C>G p.V274= | Silent (SNP) | VAF 100/343 reads (29%) | catalogued as COSV56714989, COSV56716962; called by muse, mutect2, varscan2
- NPY2R | c.858C>A p.A286= | Silent (SNP) | VAF 37/107 reads (35%) | called by muse, mutect2, varscan2
- OR10K1 | c.39C>A p.V13= | Silent (SNP) | VAF 54/249 reads (22%) | catalogued as COSV99193910; called by muse, mutect2
- OR10K1 | c.351C>A p.A117= | Silent (SNP) | VAF 136/464 reads (29%) | catalogued as COSV56873399; called by muse, mutect2, varscan2
- OR14J1 | c.480T>A p.I160= | Silent (SNP) | VAF 110/355 reads (31%) | catalogued as COSV101012818; called by muse, mutect2, varscan2
- OR2A4 | c.81T>C p.F27= | Silent (SNP) | VAF 98/625 reads (16%) | called by muse, mutect2, varscan2
- OR2M4 | c.765T>A p.A255= | Silent (SNP) | VAF 13/314 reads (4%) | called by muse, mutect2
- OR4N5 | c.201C>A p.A67= | Silent (SNP) | VAF 86/212 reads (41%) | catalogued as COSV100374192; called by muse, mutect2, varscan2
- OR5B21 | c.456C>T p.L152= | Silent (SNP) | VAF 72/410 reads (18%) | catalogued as rs751128552; called by muse, mutect2, varscan2
- OR5D18 | c.351T>A p.A117= | Silent (SNP) | VAF 94/341 reads (28%) | called by muse, mutect2, varscan2
- PCDHA6 | c.588A>G p.L196= | Silent (SNP) | VAF 174/531 reads (33%) | catalogued as COSV65352154; called by muse, mutect2, varscan2
- PEDS1 | c.495A>G p.L165= | Silent (SNP) | VAF 97/363 reads (27%) | called by muse, mutect2, varscan2
- PEG10 | c.327G>A p.R109= (on ENST00000482108 / NM_001040152.2; = p.R143= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/464 reads (23%) | called by muse, mutect2, varscan2
- PEG3 | c.93G>A p.P31= | Silent (SNP) | VAF 65/241 reads (27%) | catalogued as rs182961814, COSV55631349; called by muse, mutect2, varscan2
- PER3 | c.2043G>A p.A681= | Silent (SNP) | VAF 261/774 reads (34%) | catalogued as rs760891425; called by muse, mutect2, varscan2
- PGBD1 | c.1614C>G p.P538= | Silent (SNP) | VAF 84/497 reads (17%) | called by muse, mutect2, varscan2
- PLEC | c.4659C>T p.R1553= (on ENST00000322810 / NM_201380.4; = p.R1443= on NM_000445.5) | Silent (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- PLXND1 | c.468C>A p.I156= | Silent (SNP) | VAF 85/253 reads (34%) | called by muse, mutect2, varscan2
- POLR1A | c.3003G>C p.V1001= | Silent (SNP) | VAF 64/337 reads (19%) | called by muse, mutect2, varscan2
- POP1 | c.2766G>A p.K922= | Silent (SNP) | VAF 309/825 reads (37%) | called by muse, mutect2, varscan2
- PRSS56 | c.339C>A p.P113= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99285566; called by muse, mutect2, varscan2
- REG1B | c.357C>A p.V119= | Silent (SNP) | VAF 85/234 reads (36%) | called by muse, mutect2, varscan2
- RFPL4B | c.483C>A p.G161= | Silent (SNP) | VAF 55/395 reads (14%) | called by muse, mutect2, varscan2
- RNF32 | c.711G>A p.L237= | Silent (SNP) | VAF 76/345 reads (22%) | catalogued as COSV100311641; called by muse, mutect2, varscan2
- RYR1 | c.5337C>A p.P1779= | Silent (SNP) | VAF 114/398 reads (29%) | called by muse, mutect2, varscan2
- SCN10A | c.904C>A p.R302= | Silent (SNP) | VAF 116/334 reads (35%) | catalogued as COSV71860734; called by mutect2, varscan2
- SERPINB2 | c.966C>T p.S322= | Silent (SNP) | VAF 140/471 reads (30%) | catalogued as rs868146178, COSV99449840; called by muse, mutect2, varscan2
- SGCD | c.264C>A p.L88= (on ENST00000435422 / NM_001128209.2; = p.L89= on NM_000337.5) | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV61912710; called by muse, mutect2, varscan2
- SH3RF2 | c.1461G>A p.V487= | Silent (SNP) | VAF 244/592 reads (41%) | catalogued as rs1175867532; called by muse, mutect2, varscan2
- SLCO2B1 | c.1215A>T p.T405= | Silent (SNP) | VAF 89/243 reads (37%) | called by muse, mutect2, varscan2
- SP8 | c.204G>T p.A68= (on ENST00000361443 / NM_198956.4; = p.A86= on NM_182700.6) | Silent (SNP) | VAF 78/402 reads (19%) | called by muse, mutect2, varscan2
- SPATA31D3 | c.2592C>A p.S864= | Silent (SNP) | VAF 110/619 reads (18%) | catalogued as COSV61986348; called by muse, mutect2, varscan2
- SPIRE2 | c.546C>G p.P182= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- TACR3 | c.987T>C p.N329= | Silent (SNP) | VAF 132/384 reads (34%) | called by muse, mutect2, varscan2
- TAF2 | c.3204G>A p.P1068= | Silent (SNP) | VAF 250/702 reads (36%) | catalogued as rs767191642, COSV65417025; called by muse, mutect2, varscan2
- TEKT4 | c.723C>A p.T241= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- TYR | c.744A>T p.T248= | Silent (SNP) | VAF 70/152 reads (46%) | called by muse, mutect2, varscan2
- UBR1 | c.4692G>A p.L1564= | Silent (SNP) | VAF 87/431 reads (20%) | called by muse, mutect2, varscan2
- UNC45B | c.1722G>T p.S574= | Silent (SNP) | VAF 62/233 reads (27%) | called by muse, mutect2, varscan2
- USH2A | c.13698C>A p.T4566= | Silent (SNP) | VAF 107/491 reads (22%) | catalogued as rs867259487; called by muse, mutect2, varscan2
- XIRP2 | c.6171C>T p.H2057= (on ENST00000628543; = p.H2232= on NM_152381.6) | Silent (SNP) | VAF 109/340 reads (32%) | catalogued as rs370981896, COSV54681914; called by muse, mutect2, varscan2
- ZNF605 | c.1167A>G p.G389= | Silent (SNP) | VAF 100/341 reads (29%) | called by muse, mutect2, varscan2
- ZNF730 | c.1428G>T p.G476= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV101659602; called by muse, mutect2, varscan2
- AC016596.1 | chr5:56001765 A>G | 5'Flank (SNP) | VAF 50/189 reads (26%) | called by muse, mutect2, varscan2
- AC021218.1 | n.352G>T | RNA (SNP) | VAF 173/545 reads (32%) | called by muse, mutect2, varscan2
- AC090151.1 | chr8:54701590 T>C | 3'Flank (SNP) | VAF 142/403 reads (35%) | catalogued as rs1312734714; called by muse, varscan2
- AC244394.2 | n.1776del | RNA (DEL) | VAF 142/714 reads (20%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.188-2429G>T | Intron (SNP) | VAF 73/504 reads (14%) | called by muse, varscan2
- AGAP14P | n.671C>A | RNA (SNP) | VAF 177/629 reads (28%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+4713G>T | Intron (SNP) | VAF 21/80 reads (26%) | called by muse, varscan2
- ALG2 | c.-25G>C | 5'UTR (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- ANKRD11 | c.7470+223G>A | Intron (SNP) | VAF 124/415 reads (30%) | called by muse, mutect2, varscan2
- BCAS3 | c.2639-3280G>A | Intron (SNP) | VAF 60/394 reads (15%) | called by muse, mutect2, varscan2
- C3orf18 | c.*502A>C | 3'UTR (SNP) | VAF 138/356 reads (39%) | called by muse, mutect2, varscan2
- CFH | c.2956+27G>A | Intron (SNP) | VAF 111/400 reads (28%) | called by muse, varscan2
- CREBRF | c.1222+15G>C | Intron (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- CYP2A7P1 | n.222C>T | RNA (SNP) | VAF 85/332 reads (26%) | catalogued as rs576171764; called by muse, varscan2
- DMAC2 | chr19:41440295 G>C | 5'Flank (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- DYSF | c.3874-33C>T | Intron (SNP) | VAF 122/304 reads (40%) | called by muse, mutect2, varscan2
- EIF4A1 | c.515-129A>C | Intron (SNP) | VAF 41/152 reads (27%) | called by muse, mutect2, varscan2
- ERLIN2 | chr8:37736450 C>G | 5'Flank (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2
- ESR1 | c.-31A>T | 5'UTR (SNP) | VAF 58/408 reads (14%) | called by muse, mutect2, varscan2
- ESRRB | c.1501-24G>T | Intron (SNP) | VAF 92/236 reads (39%) | called by muse, mutect2, varscan2
- F13A1 | c.*37C>T | 3'UTR (SNP) | VAF 126/476 reads (26%) | called by muse, varscan2
- FAM20A | c.*1210C>G | 3'UTR (SNP) | VAF 127/488 reads (26%) | called by muse, mutect2, varscan2
- FAM210B | c.186+1064G>C | Intron (SNP) | VAF 47/233 reads (20%) | called by muse, mutect2, varscan2
- FRMD1 | chr6:168081413 C>T | 5'Flank (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- FUS | c.764+358G>T | Intron (SNP) | VAF 55/371 reads (15%) | called by muse, mutect2, varscan2
- FUT6 | c.*90C>T | 3'UTR (SNP) | VAF 231/974 reads (24%) | called by muse, mutect2, varscan2
- GLYCTK | c.*1109C>T | 3'UTR (SNP) | VAF 113/307 reads (37%) | called by muse, mutect2, varscan2
- HBP1 | c.-176T>G | 5'UTR (SNP) | VAF 51/245 reads (21%) | called by muse, mutect2, varscan2
- HHLA1 | c.140-1094C>A | Intron (SNP) | VAF 42/430 reads (10%) | catalogued as COSV70153812; called by muse, mutect2
- HIVEP1 | c.40+4740G>A | Intron (SNP) | VAF 81/353 reads (23%) | catalogued as rs760061469; called by muse, mutect2, varscan2
- HMGN1 | c.*292G>T | 3'UTR (SNP) | VAF 109/475 reads (23%) | called by muse, mutect2, varscan2
- HMSD | c.*49C>A | 3'UTR (SNP) | VAF 68/240 reads (28%) | called by muse, mutect2, varscan2
- HOXA10 | c.*884C>A | 3'UTR (SNP) | VAF 134/565 reads (24%) | called by muse, varscan2
- HOXB6 | c.*358G>T | 3'UTR (SNP) | VAF 97/381 reads (25%) | called by muse, mutect2, varscan2
- HTR3D | c.257+27G>C | Intron (SNP) | VAF 38/590 reads (6%) | called by muse, mutect2
- IGHV3-73 | c.-21A>T | 5'UTR (SNP) | VAF 22/624 reads (4%) | called by muse, mutect2
- IQSEC1 | c.2847+1339C>T | Intron (SNP) | VAF 168/433 reads (39%) | called by muse, varscan2
- KCTD8 | c.962-118200C>A | Intron (SNP) | VAF 53/291 reads (18%) | called by muse, mutect2, varscan2
- KIF21B | c.900+39A>C | Intron (SNP) | VAF 48/227 reads (21%) | called by muse, varscan2
- LINC01148 | n.295C>T | RNA (SNP) | VAF 29/89 reads (33%) | called by muse, mutect2, varscan2
- LINC01193 | n.754A>G | RNA (SNP) | VAF 72/293 reads (25%) | catalogued as rs1452421995; called by muse, mutect2, varscan2
- LIPI | chr21:14210822 A>G | 5'Flank (SNP) | VAF 25/170 reads (15%) | called by muse, mutect2, varscan2
- MIR1197 | n.27G>T | RNA (SNP) | VAF 19/535 reads (4%) | called by muse, mutect2
- MLXIPL | c.573+116G>T | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92594C>A | Intron (SNP) | VAF 121/299 reads (40%) | called by muse, mutect2, varscan2
- MUC19 | n.5954_5955delinsA | RNA (DEL) | VAF 65/502 reads (13%) | called by pindel, varscan2*
- MYO18A | c.1000-6283C>A | Intron (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2
- PI4KAP2 | n.2369C>T | RNA (SNP) | VAF 50/275 reads (18%) | called by muse, mutect2, varscan2
- PKD1L1 | c.*25C>T | 3'UTR (SNP) | VAF 73/301 reads (24%) | called by muse, mutect2, varscan2
- PLCB4 | c.1612-2598G>T | Intron (SNP) | VAF 46/198 reads (23%) | called by muse, mutect2, varscan2
- PON1 | c.-1del | 5'UTR (DEL) | VAF 248/993 reads (25%) | called by mutect2, pindel, varscan2
- RNU6-713P | chr12:40557163 C>T | 5'Flank (SNP) | VAF 43/317 reads (14%) | called by muse, mutect2, varscan2
- SLC2A2 | c.-2C>G | 5'UTR (SNP) | VAF 119/712 reads (17%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23756C>G | Intron (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- STX4 | chr16:31033390 A>T | 5'Flank (SNP) | VAF 115/454 reads (25%) | called by muse, mutect2, varscan2
- TBX1 | c.1009+876G>T | Intron (SNP) | VAF 47/217 reads (22%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.269-34del | Intron (DEL) | VAF 30/90 reads (33%) | called by mutect2, varscan2
- TSN | c.67-575del | Intron (DEL) | VAF 35/151 reads (23%) | called by mutect2, pindel, varscan2
- TTN | c.34264+4810A>G | Intron (SNP) | VAF 81/298 reads (27%) | catalogued as COSV60035926; called by muse, mutect2, varscan2
- UCK2 | c.-41G>C | 5'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- ZDHHC8 | c.558-18T>C | Intron (SNP) | VAF 115/556 reads (21%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+5171G>A | Intron (SNP) | VAF 50/331 reads (15%) | called by muse, mutect2, varscan2
- ZNF707 | c.256+575C>T | Intron (SNP) | VAF 218/646 reads (34%) | called by muse, varscan2
